Gene-level copy-number profile of tumor specimen TCGA-95-A4VP-01A from TCGA case TCGA-95-A4VP, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 66.1 years (24,130 days).
Specimen TCGA-95-A4VP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.dad280e3-147d-4ded-8528-1a0aa17cc25d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-95-A4VP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/52b5eae8-a1da-44c6-9f9e-a80ab3bea37d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 829; copy number 2: 30,133; copy number 3: 17,006; copy number 4: 5,715; copy number 5: 3,326; copy number 6: 2,023; copy number 7: 515; copy number 10: 84; copy number 12: 112; copy number 13: 77.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-95-A4VP-01A-21D-A25M-01): tumor purity 0.3, ploidy 2.73, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,137 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:210,676,823–211,134,165, 1 gene, copy number 5 (within-gene range 4–5): KCNH1.
- chr1:210,858,125–211,134,146, 1 gene, copy number 5 (within-gene range 4–5): AL590132.1.
- chr1:211,082,872–248,919,946, 833 genes, copy number 5 (broad region; genes not listed).
- chr2:214,241,676–242,160,153, 608 genes, copy number 5 (broad region; genes not listed).
- chr4:36,281,616–49,589,529, 215 genes, copy number 5 (broad region; genes not listed).
- chr5:150,475,531–181,342,213, 588 genes, copy number 5 (broad region; genes not listed).
- chr8:150,584–145,066,685, 2,481 genes, copy number 5–7 (broad region; genes not listed).
- chr11:79,092,848–81,431,520, 14 genes, copy number 5 (within-gene range 3–5): AP002957.1, AP001547.1, MIR708, MIR5579, AP001978.1, AP001541.1, AP001284.1, AP006295.1, RNU6-544P, ARL6IP1P3, LINC02720, AP003398.1, AP003398.2, AP003464.1.
- chr12:66,767–34,166,954, 846 genes, copy number 5 (broad region; genes not listed).
- chr14:21,351,476–43,596,683, 548 genes, copy number 6–13 (broad region; genes not listed).
- chr14:44,077,534–44,120,761, 2 genes, copy number 6: EIF4BP1, AL109766.1.

Autosomal genes at a single copy (total copy number 1): 829. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
